Surgical pathology report (de-identified scan), TCGA case TCGA-09-0369, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-0369-01A (Primary Tumor).

[page 1 of 9]
[illegible]

Journal of Management Inquiry

10

10

10

E: Falciform ligament

100

1100

110F Fleet 4

1102 East 11th

5
6
7
8
9

H8F First x 1

H&E, First x 1

100

H&E, Papanicolaou

Final Pathologic Diagnosis:

[page 2 of 9]
- A. Right ovary and fallopian tube, salpingo-oophorectomy:
- Ovary: Malignant mixed müllerian tumor (MMMT, carcinosarcoma), grade 16.0 cm in greatest dimension; see comment.
- Fallopian tube: Serosal involvement by serous carcinoma.
B. Peritoneum, bladder, biopsy: Metastatic serous carcinoma.
C. Uterus, left ovary and fallopian tube, supracervical hysterectomy and salpingo-oophorectomy:
- Endocervix: No significant pathologic abnormality.
- Endometrium:
1) Benign endometrial polyp.
2) Proliferative pattern.
- Myometrium:
1) Leiomyomata.
2) Adenomyosis.
- Serosa: Reactive mesothelial hyperplasia.
- Left fallopian tube: No significant pathologic abnormality.
- Left ovary:
1) Serous carcinoma in periovarian lymphovascular spaces.
2) Follicular cyst.
D. Peritoneum, cul de sac, biopsy: Metastatic serous carcinoma, microscopic focus.
E. Peritoneum, falciform ligament, biopsy: No tumor identified.
F. Omentum, resection: No tumor identified.
G. Bowel mesentery nodule, biopsy: Benign fibrous nodule; no tumor identified.
H. Lymph nodes, left periaortic, dissection: No tumor identified in ten lymph nodes (0/10).
I. Lymph nodes, left pelvic, dissection: No tumor identified in fourteen lymph nodes (0/14).
J. Lymph nodes, right periaortic, dissection: Metastatic serous carcinoma in two of eight lymph nodes (2/8).
K. Peritoneum, left paracolic gutter, biopsy: No tumor identified.
L. Vermiform appendix, appendectomy: No tumor identified.
M. Lymph nodes, right pelvic, dissection: No tumor identified in nine lymph nodes (0/9).
N. Peritoneum, diaphragm, biopsy: Metastatic serous carcinoma.
O. Peritoneum, right paracolic gutter, biopsy: No tumor identified.

[page 3 of 9]
Note: Sections of the ovary show a malignant mixed müllerian tumor (MMT, carcinosarcoma), homologous type, composed of a high grade serous carcinoma and malignant stromal cells. Focally, areas with clear cell morphology are seen. The differential diagnosis for these latter areas includes clear cell

carcinoma or squamous differentiation but we favor the former. The serous and stromal components are positive for p53 and WT-1 by immunohistochemistry while the clear cell component is not, further supporting the diagnosis.

While the 16 cm cystic mass in the right ovary is composed of both serous carcinoma and malignant

stroma, areas of lymphovascular space invasion of the right fallopian tube and left ovary are composed of

only the serous component. Likewise, the periaortic lymph node metastases and spread to the peritoneal

surface of the bladder, cul de sac and diaphragm show only the serous carcinoma component, as is typically seen in ovarian MMT.

Finally, there are histiocytic aggregates on several serosal surfaces (uterine serosa (part C), and parts D, G

and O) that may represent a reaction to adhesions. In part G, there is also a dense collection of fibroblasts

and parallel collagen fibers which may represent a scar. The following immunohistochemical stains were performed and evaluated on block A5:

ER: Negative; There is 1+ nuclear staining in <5% of cells.

PR: Negative; There is 1+ nuclear staining in <5% of cells.

Result of Her-2/*neu* test: Borderline for Her-2/*neu* oncoprotein over-expression.

An immunohistochemical assay was performed on block A5 using the CB11 monoclonal antibody to Her-2/*neu* oncoprotein.

The staining intensity of this carcinoma was 2 on a scale of 0-3.

Carcinomas with staining intensity scores of 0 or 1 are considered negative for over-expression of Her-2/*neu* oncoprotein.

Those with a staining intensity score of 2 are considered *borderline*. We and others have observed that many

carcinomas with staining intensity scores of 2 do not show gene amplification. All carcinomas with staining intensity scores of 2 are

therefore submitted for FISH testing. The results of the FISH test are issued directly from the molecular cytogenetics

laboratory.

Carcinomas with staining intensity scores of 3 are considered *positive* for over-expression of Her-2/*neu* oncoprotein.

Tumors in this category show an excellent correlation between the results of immunohistochemical and FISH testing, and

almost always show gene amplification.

Ovarian Tumor Synoptic Comment

1. Type of tumor: Malignant mixed müllerian tumor (MMT, carcinosarcoma).

2. Grade of tumor: 3/3.

3. Location of tumor: Unilateral, right ovary.

4. Diameter of tumor: 16 cm.

5. Appearance of surface of ovary: Tumor on surface.

6. Condition of capsule: Intact.

7. Appearance of cut surface: Solid and cystic, mainly cystic.

8. Color of solid areas: Tan.

[page 4 of 9]
9. Necrosis: Focal.
10. Lymphatic/vascular invasion: Lymphovascular space invasion in main tumor mass (right ovary and fallopian tube), as well as in per-ovarian vessels of left ovary.
11. Sites of metastases in pelvis: Bladder and cul de sac peritoneum, as well as lymphovascular spaces of left ovary.
12. Pelvic lymph nodes: No carcinoma in twenty-three lymph nodes (0/23) .
13. Sites of metastases in abdomen: Diaphragm peritoneum.
14. Para-aortic lymph nodes: Metastatic carcinoma in two of eighteen lymph nodes (2/18).
15. Peritoneal cytology: Positive for metastatic adenocarcinoma in pelvic and diaphragm washings
16. Other significant findings: Not identified.
17. FIGO stage: IIIC.
18. TNM stage: pT3cN1Mx.

has reviewed selected slides from this case and concurs with the diagnosis above.

Intraoperative Consult Diagnosis

FS1 (A) Right adnexal mass, resection: Carcinoma with atypical stromal cells; defer classification to permanent section.

Clinical History

The patient is a [REDACTED] with a right adnexal mass, who undergoes hysterectomy and bilateral salpingo-oophorectomy, as well as lymph node dissections and peritoneal biopsies.

Gross Description

The specimen is received in fifteen parts, each labeled with the patient's name and medical record number.

Parts B-O are received in formalin.

Part A, received fresh, is labeled "right adnexal mass," and consists of an ovary and fallopian tube, weighing 1500 gm and measuring 16.0 x 14.0 x 10.0 cm. On the surface of the ovary is a papillary, pink,

2.0-cm

mass. The ovarian surface is otherwise pink, smooth, and unremarkable. The ovary itself is composed of a

unilocular cyst with tan, papillary mass, measuring 6.0 cm in greatest dimension. A portion of the mass is

submitted for frozen section 1. Additional material is taken for tumor banking and for Oncotech.

The fallopian tube measures 5.5 cm in length with an average diameter of 0.4 cm. The fimbriae appear normal.

Normal ovarian tissue is not identified. The serosal surface opposite the papillation is inked blue. A second

soft, solid mass is identified, measuring 1.8 cm in greatest dimension. The mass appears to be encapsulated. Representative sections are submitted as follows:

Cassette A1: Frozen section remnant.

Cassette A2: Mass on surface of the ovary.

[page 5 of 9]
Cassettes A3-A5: Representative sections of papillary mass on the inside of the ovary.

Cassette A6: Representative sections of fallopian tube.

Part B, additionally labeled "bladder peritoneum," consists of a single, unoriented fragment of brown-yellow, fibrofatty tissue measuring 7.0 x 3.5 x 0.4 cm. Much of this sheet of tissue appears to consist of unremarkable adipose tissue, however, there is a white, firm, 3.5 x 2.0 x 1.0 cm nodule on one aspect of the specimen. Representative sections through this nodule are submitted in cassette B1.

Part C, additionally labeled "uterus and left ovary and tube," consists of a supracervical hysterectomy specimen with attached left adnexa, weighing 106 gm. The uterus measures 7.0 cm from fundus to supracervical hysterectomy margin, 4.5 cm from cornu to cornu, 4.0 cm from anterior to posterior and is oriented by the peritoneal reflections. The serosa is smooth. The uterine cavity sounds to 4.0 cm. The uterus is opened along the lateral borders to reveal an endometrium that is tan, measures 0.1 cm in thickness, and contains a single, 1.0 cm endometrial polyp near the fundus. The myometrium measures 1.1 cm and contains two small, apparent intramural leiomyomas, measuring 0.5 cm in greatest dimension, each. The left fallopian tube measures 4.0 cm in length and 0.7 cm in average diameter. The fimbriae are lush. On cut section, the tube is unremarkable. The left ovary measures 3.0 x 1.7 x 1.0 cm. The surface is wrinkled. On cut section, the ovary has a 1.1 cm thin-walled, possible follicular cyst. No other lesions are noted, grossly. Representative sections are submitted as follows:

Cassette C1: Anterior supracervical hysterectomy margin, perpendicular.

Cassette C2: Posterior supracervical hysterectomy margin, perpendicular.

Cassette C3: Anterior endometrium with endometrial polyp and nearby leiomyoma.

Cassette C4: Posterior endometrium with endometrial polyp.

Cassette C5: Anterior endometrium, possibly lower uterine segment, with adjacent small leiomyoma.

Cassette C6: Additional section of posterior endometrium with endometrial polyp, appearing to protrude slightly into myometrium.

Cassette C7: Representative sections of left ovary.

Cassette C8: Representative sections of left fallopian tube.

Part D, additionally labeled "cul-de-sac peritoneum," consists of a single unoriented, relatively flat sheet of brown-yellow, fibrofatty tissue measuring 5.0 x 2.0 x 0.4 cm. One surface appears to consist of unremarkable, yellow adipose tissue, while the other has a nodular brown, relatively firm mass, measuring 3.0 x 1.0 x 0.5 cm. Representative sections are submitted in cassette D1.

Part E, additionally labeled "falciiform ligament," consists of a single unoriented fragment of yellow-white, soft adipose tissue measuring 5.5 x 6.0 x 1.5 cm. A portion of this adipose tissue appears to be covered by a thin, transparent membrane. No focal masses or lesions are noted. Representative sections are submitted in cassette E1.

Part F, additionally labeled "omentum," consists of a single, unoriented, large, flat sheet of yellow adipose tissue measuring 24.0 x 17.0 x 0.5 cm. No focal lesions or masses are noted. Representative

[page 6 of 9]
sections are submitted in cassette F1. Part G, additionally labeled "bowel mesentery nodule," consists of a single small, unoriented fragment of yellow-white, soft tissue measuring 0.4 x 0.2 x 0.1 cm. The specimen is wrapped in tissue paper and entirely submitted in cassette G1. Part H, additionally labeled "left peri-aortic lymph nodes," consists of a single unoriented, somewhat linear fragment of yellow-brown, fibrofatty tissue measuring 7.2 x 1.2 x 0.8 cm. Candidate lymph nodes are dissected free from the minimal, associated fat, and the specimen is submitted as follows: Cassettes H1-H2: Candidate lymph nodes, in entirety. Cassettes H3-H4: A single candidate lymph node, bisected. Part I, additionally labeled "left pelvic lymph nodes," consists of multiple, unoriented fragments of yellow-brown, fibrofatty tissue measuring 3.0 x 3.0 x 0.7 cm in aggregate. Candidate lymph nodes are dissected free from the fat, and the specimen is entirely submitted in cassettes I1-I3. Part J, additionally labeled "right peri-aortic lymph nodes," consists of multiple, unoriented fragments of yellow-brown, fibrofatty tissue measuring 3.0 x 2.5 x 0.6 cm in aggregate. Candidate lymph nodes are dissected free from the fat, and the specimen is entirely submitted in cassettes J1-J2. Part K, additionally labeled "left paracolic gutter biopsy," consists of a single, unoriented fragment of yellow, soft tissue measuring 0.8 x 0.4 x 0.2 cm. The specimen is wrapped, and entirely submitted in cassette K1. Part L, additionally labeled "appendix," consists of an unremarkable vermiform appendix measuring 5.5 cm in length, 0.4 cm in average diameter, associated with a moderate amount of periapendicular fat. No lesions are noted. Sections reveal an unremarkable appendix. The appendiceal stump is inked in black. Representative sections are submitted in cassette L1. Part M, additionally labeled "right pelvic nodes," consists of multiple, unoriented fragments of yellow-brown, fibrofatty tissue measuring 4.0 x 3.2 x 0.7 cm in aggregate. Candidate lymph nodes are dissected free from the fat and submitted as follows: Cassettes M1-M2: Small candidate lymph nodes, in entirety. Cassettes M3-M4: Single larger candidate lymph nodes, bisected, with one each in M3-M4. Part N, additionally labeled "diaphragm biopsy," consists of two, unoriented fragments of yellow-brown, soft tissue measuring 0.7 x 0.3 x 0.2 cm in aggregate. The specimen is wrapped and entirely submitted in cassette N1. Part O, additionally labeled "right paracolic gutter biopsy," consists of a single, unoriented fragment of brown, soft tissue measuring 0.5 x 0.2 x 0.2 cm. The specimen is wrapped and entirely submitted in cassette O1. The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]

[page 7 of 9]
[REDACTED]

[REDACTED] have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing.

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep Imaged
Final Diagnosis
Vaginal, Thin Prep Imaged
NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.
SPECIMEN ADEQUACY:
Satisfactory for evaluation.

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep Imaged
Final Diagnosis
Vaginal, Thin Prep Imaged
NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.
SPECIMEN ADEQUACY:
Satisfactory for evaluation.

[page 8 of 9]
Specimen(s) Received: A: Retroperitoneal tumor, B: Spleen, Resection

Final Diagnosis

- A. Retroperitoneal tumor, resection: Metastatic malignant mixed mesodermal tumor (carcinosarcoma).
B. Spleen, splenectomy:
1. Metastatic malignant mixed mesodermal tumor (carcinosarcoma); see comment.
2. No tumor in four lymph nodes (0/4).

Specimen(s) Received: Cervical, Thin Prep

Final Diagnosis

Cervical, Thin Prep
NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.
SPECIMEN ADEQUACY:
Satisfactory for evaluation.
No transformation zone components are identified.

Specimen(s) Received: Cervical, Thin Prep

Final Diagnosis

Cervical, Thin Prep
NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.
Reactive cellular changes.
Atrophic changes
SPECIMEN ADEQUACY:
Satisfactory for evaluation; atrophic pattern with no identifiable endocervical/transformation zone component.

Specimen(s) Received: A: Pelvic Washing, B: Diaphragmatic Wash

Final Diagnosis

A: Pelvic Washing
ADENOCARCINOMA, METASTATIC.

[page 9 of 9]
B : Diaphragmatic Wash
ADENOCARCINOMA, METASTATIC.

Specimen(s) Received: Cervical, Thin Prep

Final Diagnosis

Cervical, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY,
SPECIMEN ADEQUACY:

Satisfactory for evaluation.

Transformation zone components are present.

Specimen(s) Received: Cytology, GYN, Site Not Specified, Thin Prep

Final Diagnosis

Cytology, GYN, Site Not Specified, Thin Prep

BENIGN CELLULAR CHANGES.

Keratoctic reaction.

SPECIMEN ADEQUACY:

Satisfactory for evaluation. Endocervical cells present.

Source: NCI Genomic Data Commons file 796d061a-a487-4349-96db-4283639db356 (TCGA-09-0369.C052E190-B5C2-44BF-B5B0-2B37CDE18CEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).